CCDI case PBCDLD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5a98c225-672f-40ce-8943-4b2c6e72e935

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.1 years (6,615 days).

Biospecimens (2 samples)
- Sample 0DPAOD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPAOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
